Somatic mutation profile of tumor specimen TCGA-DU-A7TJ-01A (aliquot TCGA-DU-A7TJ-01A-11D-A34J-08) from TCGA case TCGA-DU-A7TJ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 55.8 years (20,394 days).
Specimen TCGA-DU-A7TJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a8cf65e-4fd7-4aa8-9a9d-a89dcd19c6e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A7TJ-10A (Blood Derived Normal), aliquot TCGA-DU-A7TJ-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f79c65d-7fa6-4ddf-b333-37d75d40ad95

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1745+1del p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (DEL) | VAF 24/67 reads (36%) | hotspot (GDC flag); catalogued as COSV57129726; called by pindel, varscan2
- ACTBL2 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.006); catalogued as rs762367137, COSV70661083; called by muse, mutect2, varscan2
- ADH1C | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs572227882, COSV72892969; called by muse, mutect2, varscan2
- AOPEP | c.2418G>A p.M806I (on ENST00000375315 / NM_001193329.1; = p.M707I on NM_032823.5) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as COSV99951011; called by muse, mutect2, varscan2
- CACNA1B | c.4670A>T p.E1557V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99500191; called by muse, mutect2, varscan2
- CHIA | c.784G>A p.V262I (on ENST00000343320; = p.V154I on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as rs367730751; called by muse, mutect2, varscan2
- CHRNG | c.1310C>A p.A437D | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as COSV101264045; called by muse, mutect2, varscan2
- CRAMP1 | c.2741C>G p.S914C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99246459; called by muse, mutect2, varscan2
- EID2B | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100411062; called by muse, mutect2, varscan2
- GABRA4 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 46/130 reads (35%) | catalogued as COSV99974762; called by muse, mutect2, varscan2
- KLRC4 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100511363; called by muse, mutect2, varscan2
- MCM6 | c.1078+1G>C p.X360_splice | Splice Site (SNP) | VAF 47/129 reads (36%) | catalogued as COSV99919424; called by muse, mutect2, varscan2
- MROH2B | c.3989C>G p.T1330R | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV101270950; called by muse, mutect2, varscan2
- OR10G8 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs756655164, COSV70908457; called by muse, mutect2, varscan2
- OR1N1 | c.523T>C p.F175L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100509859; called by muse, mutect2, varscan2
- OR4K13 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs149397731; called by muse, mutect2, varscan2
- OR9G4 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100265283, COSV57247568; called by muse, mutect2, varscan2
- PFKL | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100827313; called by muse, mutect2, varscan2
- PPIL2 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756285545, COSV100622795; called by muse, mutect2, varscan2
- RPL5 | c.232G>C p.A78P | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100240533; called by muse, mutect2, varscan2
- SFTPA2 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs758513334, COSV100958868, COSV64882872; called by muse, mutect2, varscan2
- SLC26A3 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776026508, COSV60641544; called by muse, mutect2, varscan2
- SPEF1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs201214511, COSV101124240; called by muse, varscan2
- TMEM130 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs781989024, COSV59560838; called by muse, mutect2, varscan2
- TNFSF13B | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV101022411; called by muse, mutect2, varscan2
- TRIM15 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs779955260, COSV100938787; called by muse, mutect2, varscan2
- TRIM17 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as rs369849895; called by muse, mutect2, varscan2
- IGKV1-6 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- IGLV3-22 | c.158G>T p.W53L | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MIA2 | c.176dup p.L59Ffs*6 | Frame Shift Ins (INS) | VAF 36/80 reads (45%) | called by mutect2, varscan2
- PIK3R1 | c.1743_1744del p.L581Ffs*20 (on ENST00000521381 / NM_181523.3; = p.L311Ffs*20 on NM_181504.4) | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by pindel, varscan2
- PRAMEF14 | c.896A>G p.E299G | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ARHGAP27 | c.1782C>T p.H594= (on ENST00000428638 / NM_001282290.1; = p.H253= on NM_199282.3) | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs138914274; called by muse, mutect2, varscan2
- IGF2BP1 | c.1155G>A p.P385= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs369774252; called by muse, mutect2, varscan2
- LPIN2 | c.372A>G p.K124= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as COSV99859059; called by muse, mutect2, varscan2
- MTUS2 | c.2040C>T p.H680= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs201916985; called by muse, mutect2, varscan2
- MYO7B | c.1374C>T p.N458= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs374298824; called by muse, mutect2, varscan2
- OR5C1 | c.753C>T p.A251= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs374393066, COSV65456749; called by muse, mutect2, varscan2
- PTGFRN | c.780G>A p.Q260= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV67799601; called by muse, mutect2, varscan2
- PXMP4 | c.9C>G p.A3= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99459513; called by muse, mutect2, varscan2
- TTN | c.58203T>C p.N19401= (on ENST00000591111; = p.N11977= on NM_003319.4) | Silent (SNP) | VAF 15/307 reads (5%) | catalogued as COSV100632836; called by muse, mutect2
- USP36 | c.1590C>T p.D530= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs775407082, COSV100361887; called by muse, mutect2, varscan2
- ETNK1 | c.-171A>G | 5'UTR (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99861049; called by muse, mutect2, varscan2
